Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A6JD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A6JD-01A (Primary Tumor).

[page 1 of 4]
Deceased F

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) RIGHT NECK DISSECTION LEVELS IA AND IB:

Ten lymph nodes, no tumor present (0/10)
Salivary gland, no tumor present

(B) ANTERIOR BONE MARGIN:

Pending for decalcification, an addendum report will follow

(C) FLOOR OF MOUTH MARGIN:

Squamous mucosa and salivary gland
No tumor present

(D) POSTERIOR BONE MARGIN:

Pending for decalcification, an addendum report will follow

(E) RIGHT SEGMENTAL MANDIBULECTOMY, FLOOR OF MOUTH RESECTION:

INVASIVE SQUAMOUS CARCINOMA -- Poorly differentiated with sarcomatoid features

Tumor Features:

Gross: Exophytic

Size: 3.0 cm in largest dimension

Invasion: Present, depth 1.3 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Absent

Vascular Invasion: Absent

Lymphocyte Infiltration: Moderate

Bone pending for decalcification, an addendum report will follow

(F) ANTERIOR BUCCAL MUCOSA MARGIN:

Fibroadipose tissue and small fragment of skeletal muscle
No tumor present

(G) POSTERIOR BUCCAL MUCOSA MARGIN:

Focal dysplasia, not tumor present

(H) POSTERIOR GINGIVA:

INVASIVE SQUAMOUS CARCINOMA

(I) ANTERIOR GINGIVA:

Squamous mucosa
No tumor present

(J) RIGHT NECK DISSECTION LEVEL II:

Eight lymph nodes, no tumor present (0/8)

(K) RIGHT NECK DISSECTION LEVEL III:

Five lymph nodes, no tumor present (0/5)

(L) POSTERIOR GINGIVA #2:

CCF ICD-O-3
Carcinoma, squamous cell NOS
path 8070/3
Carcinoma, squamous cell
sarcomatoid 8074.3
Site Floor mouth NOS
104.9
JW819/13

[page 2 of 4]
Deceased F

Accession:

Specimen Date/Time:

Squamous mucosa with chronic inflammation

No tumor present

(M) POSTERIOR GINGIVA #3.

Squamous mucosa, salivary gland and skeletal muscle with chronic inflammation

No tumor present

GROSS DESCRIPTION

(A) RIGHT NECK DISSECTION LEVELS IA AND IB – Fragment of soft, fibrous tissue (7.3 x 1.4 x 1.2 cm) bears a single unremarkable, tan, lobulated salivary gland (1.6 x 1.4 x 0.9 cm) and multiple possible lymph nodes.

SECTION CODE: A1, one lymph node; A2, four possible lymph nodes; A3, one lymph node; A4, one lymph node; A5, one lymph node; A6, one lymph node; A7, one lymph node; A8, fibrofatty tissue with possible lymph nodes; A9, one possible lymph node.

(B) ANTERIOR BONE MARGIN, INK AT MARGIN – A tan-white fragment of bone with scant soft tissue surrounding (1.7 x 1.1 x 0.4 cm), the white bone has scant marrow. Two touch preps for immediate assessment are prepared. The remainder is sent to the bone lab for further evaluation.

SECTION CODE: B1, entire specimen, submitted en face, for decalcification.

*TP/DX: NO DEFINITE CARCINOMA, TOUCH PREP.

(C) FLOOR OF MOUTH MARGIN, MARGIN INKED – A segment of tan-pink soft tissue (2.5 x 0.3 x 0.3 cm), entirely submitted for frozen section diagnosis, C1, ink side down.

*FS/DX: NEGATIVE FOR CARCINOMA.

(D) POSTERIOR BONE MARGIN, TOUCH PREP – A portion of tan-white solid bone (1.3 x 0.8 x 0.4 cm). A touch prep is made for frozen section diagnosis. The bone is reinked and entirely submitted for decalcification in D1.

*TP/DX: NO CARCINOMA IDENTIFIED.

(E) RIGHT SEGMENTAL MANDIBULECTOMY, FLOOR OF MOUTH RESECTION, STITCH ANTERIOR – A segment of mandible (4.0 x 1.5 x 1.0 cm) with portion of the floor of the mouth (4.0 x 2.0 x 1.5 cm) and attached gingiva on the mandible (4.0 x 1.5 x 1.0 cm). A white exophytic tumor (3.0 x 2.0 x 1.0 cm) is at the floor of the mouth extending to the lingual gingiva. Tumor and possible normal tissue are submitted to tissue bank. Sectioning reveals the tumor is 1.3 cm deep invading into the mandible.

SECTION CODE: E1-E5, floor of the mouth from anterior to posterior, entirely submitted; E6-E10, lingual gingiva from anterior to posterior, entirely submitted.

E11, anterior mandible margin, en face, for decalcification; E12, E13, entire posterior mandible margin, perpendicularly sectioned to include tumor, submitted for decalcification; E14, representative sections of tumor to mandible bone, submitted for decalcification.

(F) ANTERIOR BUCCAL MUCOSA MARGIN, MARGIN INKED – A tan-pink tissue fragment (1.4 x 0.4 x 0.4 cm). Entirely submitted for frozen section diagnosis, ink side down in F1.

*FS/DX: NEGATIVE FOR CARCINOMA.

(G) POSTERIOR BUCCAL MUCOSA MARGIN, MARGIN INKED – A tan-pink tissue fragment (1.5 x 0.7 x 0.4 cm). Entirely submitted for frozen section diagnosis, ink side down in G1.

*FS/DX: DYSPLASIA, NO INVASIVE CARCINOMA.

(H) POSTERIOR GINGIVA – A tan-pink tissue fragment (0.8 x 0.6 x 0.4 cm). Entirely submitted for frozen section diagnosis, ink side down.

*FS/DX: INVASIVE SQUAMOUS CELL CARCINOMA.

(I) ANTERIOR GINGIVA – A tan-pink tissue fragment (1 x 0.3 x 0.2 cm). Entirely submitted for frozen section diagnosis in I1, ink side down.

*FS/DX: NEGATIVE FOR TUMOR.

(J) RIGHT NECK DISSECTION LEVEL II – Fragment of soft fibrous tissue (8 x 3.4 x 0.8 cm). Serial sections reveal multiple possible lymph nodes.

SECTION CODE: J1, one lymph node; J2, one lymph node; J3, two lymph nodes; J4, two lymph nodes; J5, one lymph node; J6, two lymph nodes.

(K) RIGHT NECK DISSECTION LEVEL III – Fragment of soft fibrous tissue (4.5 x 3.5 x 0.5 cm). Serial sections reveal multiple possible lymph nodes.

[page 3 of 4]
Accession:

Deceased F

Specimen Date/Time:

SECTION CODE: k1, one lymph node; K2, one lymph node; K3, one lymph node; K4, one lymph node; K5, one lymph node; K6, one lymph node.

(L) POSTERIOR GINGIVA #2 – A (0.8 x 0.3 x 0.2 cm) strip of tan pink mucosa. Specimen is submitted en face in L for frozen section.

*FS/DX: NO INVASIVE CARCINOMA IDENTIFIED.

(M) POSTERIOR GINGIVA #3 – Fragment of cauterized soft tissue (1.6 x 0.9 x 0.5 cm). The fragment is submitted entirely block M1.

SNOMED CODES

T-51200, M-80703, M-43000, "Some tests reported here may have been developed and performance characteristics determined by these tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 4 of 4]
Deceased F

Accession:

Specimen Date/Time:

ADDENDUM

This modified report is being issued to report the results of decalcification.

Addendum completed by

DIAGNOSIS

(B) ANTERIOR BONE MARGIN:

Bone, negative for tumor.

(D) POSTERIOR BONE MARGIN:

Bone, negative for tumor.

(E) RIGHT SEGMENTAL MANDIBULECTOMY, FLOOR OF MOUTH RESECTION:

Additional findings:

SQUAMOUS CARCINOMA INVADES BONE

Entire report and diagnosis completed by:

-----END OF REPORT-----

Criteria	hw 6/19/13	Yes	No
HISTOAA Discrepancy			

Source: NCI Genomic Data Commons file 95187c6d-339c-4cfc-bd13-c7dbfea75dab (TCGA-CV-A6JD.371833A3-6A9B-4EF3-9389-D20705341D28.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).